Somatic mutation profile of tumor specimen ALCH-AD75-TTP1-A (aliquot ALCH-AD75-TTP1-A-1-0-D-A509-36) from ALCHEMIST case ALCH-AD75, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.4 years (19,876 days).
Specimen ALCH-AD75-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e227f6e5-1ba8-4a6c-af9c-fb4fc80f6c63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AD75-NB1-A (Blood Derived Normal), aliquot ALCH-AD75-NB1-A-1-0-D-A509-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ca2f7be-b79b-4ae7-bd10-8a8fb35af5fe

The open-access MAF lists 62 somatic variants for this specimen: 38 protein-altering or splice-affecting, 17 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 17, Nonsense Mutation 4, Splice Site 3, Intron 2, 3'UTR 2, RNA 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 213/895 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 63/254 reads (25%) | catalogued as rs1567555994, CM156961, COSV52702138, COSV53867973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMER3 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs368379439; called by muse, mutect2
- CWH43 | c.44-2_45del p.X15_splice | Splice Site (DEL) | VAF 7/61 reads (11%) | catalogued as rs1194013221; called by mutect2, pindel*
- DNAH17 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 34/474 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.651); catalogued as rs777329899, COSV67752513; called by muse, mutect2
- FHAD1 | c.1517G>T p.R506L | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV62715580; called by muse, mutect2
- FHAD1 | c.3446G>A p.R1149H | Missense Mutation (SNP) | VAF 50/622 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs770643908, COSV58990308; called by muse, mutect2
- FTSJ1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 55/308 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs571791486, COSV50026314; called by muse, mutect2, varscan2
- IDH3B | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 80/842 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886043702; ClinVar: uncertain significance; called by muse, mutect2
- KCNG1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 42/558 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1386260978, COSV65368626; called by muse, mutect2
- NPY1R | c.689G>T p.C230F | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56715555; called by muse, mutect2
- OGDHL | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 77/619 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs757087426, COSV65105583; called by muse, mutect2, varscan2
- PGK2 | c.674A>G p.K225R | Missense Mutation (SNP) | VAF 39/823 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs186743372; called by muse, mutect2
- TONSL | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs771375609, COSV68047562; called by muse, mutect2, varscan2
- ABCA2 | c.784C>G p.P262A (on ENST00000614293; = p.P232A on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.024); called by muse, mutect2
- ACOD1 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 26/544 reads (5%) | called by muse, mutect2
- ARHGAP25 | c.607G>A p.G203R (on ENST00000409202 / NM_001007231.3; = p.G195R on NM_014882.3) | Missense Mutation (SNP) | VAF 40/734 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- CCDC144A | c.4099-1G>A p.X1367_splice | Splice Site (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- CDC7 | c.965C>A p.A322E | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2
- CDH12 | c.2287C>A p.Q763K | Missense Mutation (SNP) | VAF 107/802 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CERCAM | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 34/483 reads (7%) | called by muse, mutect2
- CXorf38 | c.761T>A p.I254K | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2
- ENTR1 | c.677C>T p.S226F (on ENST00000357365 / NM_001039707.2; = p.S203F on NM_006643.4) | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.739); called by muse, mutect2
- FAM234A | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- FAM83C | c.1607C>A p.P536H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by mutect2, varscan2
- GARS1 | c.1790A>G p.E597G | Missense Mutation (SNP) | VAF 17/428 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- GRIK1 | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 84/439 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HAVCR2 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 25/427 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HERC1 | c.6875C>T p.S2292L | Missense Mutation (SNP) | VAF 46/379 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- KAT2B | c.257C>A p.P86Q | Missense Mutation (SNP) | VAF 17/311 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NTRK1 | c.2018G>C p.R673T | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2
- PTPRN | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RCC1 | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2
- SCN11A | c.3057G>T p.L1019F | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- ST6GALNAC6 | c.26+2T>G p.X9_splice | Splice Site (SNP) | VAF 15/293 reads (5%) | called by muse, mutect2
- STYK1 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TCEAL3 | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 40/496 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); called by muse, mutect2
- ZFYVE26 | c.2937C>A p.C979* | Nonsense Mutation (SNP) | VAF 44/958 reads (5%) | called by muse, mutect2
- BMPR2 | c.1593G>C p.L531= | Silent (SNP) | VAF 26/332 reads (8%) | called by muse, mutect2
- CNGA2 | c.1761C>T p.N587= | Silent (SNP) | VAF 12/258 reads (5%) | catalogued as rs1438330633, COSV61705005; called by muse, mutect2
- CORO1A | c.1222C>A p.R408= | Silent (SNP) | VAF 20/297 reads (7%) | catalogued as rs373093101; called by muse, mutect2
- DNAH11 | c.622A>C p.R208= | Silent (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- ERAL1 | c.931C>T p.L311= | Silent (SNP) | VAF 78/537 reads (15%) | catalogued as COSV54740437; called by muse, mutect2, varscan2
- FLG | c.1374A>G p.S458= | Silent (SNP) | VAF 42/684 reads (6%) | catalogued as rs1557881605; called by muse, mutect2
- IFI27L2 | c.336T>C p.N112= | Silent (SNP) | VAF 31/265 reads (12%) | called by muse, mutect2, varscan2
- IGLON5 | c.837C>G p.A279= | Silent (SNP) | VAF 9/212 reads (4%) | called by muse, mutect2
- IGLV2-8 | c.120C>T p.S40= | Silent (SNP) | VAF 118/1681 reads (7%) | catalogued as rs1449887609; called by muse, mutect2
- NAPSA | c.1050C>T p.G350= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV53798317; called by mutect2, varscan2
- OR13A1 | c.423C>T p.Y141= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as rs1324546991, COSV100980963; called by muse, mutect2
- PKD1 | c.7929C>T p.R2643= | Silent (SNP) | VAF 36/925 reads (4%) | called by muse, mutect2
- PTPN14 | c.1986C>T p.H662= | Silent (SNP) | VAF 24/182 reads (13%) | called by muse, varscan2
- PXK | c.909G>C p.L303= | Silent (SNP) | VAF 24/519 reads (5%) | called by muse, mutect2
- RETNLB | c.18C>T p.C6= | Silent (SNP) | VAF 22/124 reads (18%) | called by muse, mutect2, varscan2
- SCN5A | c.447C>A p.A149= | Silent (SNP) | VAF 14/340 reads (4%) | called by muse, mutect2
- VAT1L | c.450G>A p.P150= | Silent (SNP) | VAF 121/1324 reads (9%) | catalogued as rs369885557; called by muse, mutect2
- AC005400.1 | n.87-20750G>A | Intron (SNP) | VAF 13/347 reads (4%) | called by muse, mutect2
- AC011487.2 | n.1288A>T | RNA (SNP) | VAF 46/376 reads (12%) | called by muse, mutect2, varscan2
- C19orf12 | c.24-37C>T | Intron (SNP) | VAF 32/530 reads (6%) | called by muse, mutect2
- KLF6 | c.*1289G>T | 3'UTR (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- KLF6 | c.*1288G>T | 3'UTR (SNP) | VAF 15/192 reads (8%) | called by muse, mutect2
- SCNN1D | c.-109C>G | 5'UTR (SNP) | VAF 20/308 reads (6%) | catalogued as COSV57641309; called by muse, mutect2
- SLC9A7P1 | n.319C>T | RNA (SNP) | VAF 26/649 reads (4%) | called by muse, mutect2
